Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MG-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: UTERUS WITH BILATERAL ADNEXA, VAGINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. WELL-DIFFERENTIATED ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE WITH SQUAMOUS METAPLASIA, FIGO GRADE 1.
- B. TUMOR MEASURES 4.5 CM IN GREATEST DIMENSION.
- C. TUMOR INVOLVES 80% OF ANTERIOR AND 50% OF POSTERIOR ENDOMETRIUM.
- D. TUMOR INVADERS 36% OF MYOMETRIUM (0.8 CM OUT OF 2.2 CM OF MYOMETRIAL THICKNESS).
- E. TUMOR INVOLVES ENDOCERVICAL GLANDULAR EPITHELIUM WITHOUT CERVICAL STROMAL INVASION.
- F. NO DEFINITE LYMPHOVASCULAR INVASION IS IDENTIFIED.
- G. ADENOMYOSIS.
- H. OVARIES, LEFT AND RIGHT, WITH PHYSIOLOGIC CHANGES.
- I. FALLOPIAN TUBES, LEFT AND RIGHT, UNREMARKABLE.

PART 2: RIGHT PELVIC LYMPH NODES, DISSECTION - TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 3: RIGHT OBTURATOR LYMPH NODES, DISSECTION - ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 4: RIGHT COMMON ILIAC LYMPH NODES, DISSECTION - ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 5: RIGHT PERIAORTIC LYMPH NODES, DISSECTION - ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 6: LEFT PELVIC LYMPH NODE, DISSECTION - ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 7: LEFT COMMON ILIAC LYMPH NODES, DISSECTION - A. FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR. B. NO LYMPHOID TISSUE IS IDENTIFIED.

PART 8: LEFT PERIAORTIC LYMPH NODES, DISSECTION - ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 9: OMENTUM, BIOPSY - FIBROVASCULAR AND FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

100-0-3

Adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium C54.1

for 5/3/11

COMMENT:

Companion pelvic wash cytology specimen [REDACTED] is negative for malignant cells.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS
TUMOR SIZE: Maximum dimension: 4.5 cm
PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT: Anterior endomyometrium: 80 %, Posterior endomyometrium: 50 %
DEPTH OF INVASION:** Less than 1/2 thickness of myometrium
STRUCTURES INVOLVED: Endocervical glands
ANGIOLYMPHATIC INVASION: No
OTHER: (epithelial, smooth muscle, others), Adenomyosis
LYMPH NODES POSITIVE: Number of lymph nodes positive:: 0
LYMPH NODES EXAMINED: Total number of lymph nodes examined: 7
T STAGE, PATHOLOGIC: pT2a
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
FIGO STAGE: IIA

Source: NCI Genomic Data Commons file 29cb5530-795f-4180-91ef-afa1ff7d9fbf (TCGA-BG-A0MG.65A0B84A-72AD-42E2-B0DB-DA8D2BD54E9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).